Somatic mutation profile of tumor specimen TCGA-2G-AAKM-01A (aliquot TCGA-2G-AAKM-01A-11D-A42Y-10) from TCGA case TCGA-2G-AAKM, project TCGA-TGCT (Testicular Germ Cell Tumors). Sex at birth: male; Vital status: Dead; Primary diagnosis: Mixed germ cell tumor; Tissue or organ of origin: Testis, NOS; AJCC pathologic stage: Stage II; Age at diagnosis: 14.6 years (5,321 days).
Specimen TCGA-2G-AAKM-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 9317ce01-232e-4880-97fe-e79011d30c62.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-2G-AAKM-10A (Blood Derived Normal), aliquot TCGA-2G-AAKM-10A-01D-A433-10; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/b01a9fa0-db22-4ab6-ba46-c52ce8c373e0

The open-access MAF lists 6 somatic variants for this specimen: 4 protein-altering or splice-affecting, 1 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 3, Silent 1, 5'Flank 1, Frame Shift Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CTAGE1 | c.473C>G p.A158G | Missense Mutation (SNP) | VAF 24/75 reads (32%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.767); catalogued as rs771599949; called by muse, mutect2, varscan2
- GJA1 | c.365A>G p.N122S | Missense Mutation (SNP) | VAF 39/162 reads (24%) | SIFT tolerated (0.8); PolyPhen benign (0.001); catalogued as rs769704488; called by muse, mutect2, varscan2
- RPAIN | c.110G>C p.R37P | Missense Mutation (SNP) | VAF 13/119 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.919); catalogued as rs562693433; called by muse, mutect2, varscan2
- BUD31 | c.255del p.D85Efs*4 | Frame Shift Del (DEL) | VAF 13/114 reads (11%) | called by mutect2, pindel, varscan2
- TAS1R3 | c.1893C>T p.A631= | Silent (SNP) | VAF 3/40 reads (8%) | called by muse, mutect2
- TENT5A | chr6:81752730 C>A | 5'Flank (SNP) | VAF 14/49 reads (29%) | called by muse, mutect2, varscan2
